Surgical pathology report (de-identified scan), TCGA case TCGA-44-6148, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-6148-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Level 10
- B. Left lower lobe
- C. Left upper lobe lymph node
- D. Subcarinal lymph node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung carcinoma

GROSS DESCRIPTION

- A. Received fresh labeled "level 10" is a 2.2 x 1.4 x 0.6 cm. rubbery tan gray-black tissue in keeping with lymph node which is bisected and entirely submitted in one block.
- B. Received fresh for tissue procurement labeled "left lower lobe" is a 232 gram, 21.0 x 11.0 x 5.5 cm. lobectomy specimen with attached, 1 cm. in length, 2.5 x 0.9 cm. in diameter bronchial stump. The pleura is smooth to wrinkled tan pink-purple. A palpable mass is noted along the lateral aspect. On sectioning, there is a well-circumscribed 3.0 x 2.8 x 2.8 cm. congested pale tan/mucoid tumor mass which focally extends to within 0.3 cm. of the pleural surface (inked blue). A portion of tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The parenchyma throughout the remainder of the specimen is spongiform tan pink-red without additional mass lesion or abnormality. A single 0.4 cm. gray black tissue in keeping with lymph node is recovered from the hilum. Representative sections are submitted in nine blocks as labeled. [REDACTED]

BLOCK SUMMARY: 1 - Bronchial stump margin; 2 - vascular margins; 3-5 - tumor to inked pleural surface; 6 - tumor to normal parenchyma; 7 and 8 - random normal; 9 - one whole hilar lymph node.

- C. Received fresh labeled "left upper lobe lymph node" is a 0.6 x 0.5 x 0.35 cm. slightly rubbery gray black tissue in keeping with lymph node which is bisected and entirely submitted in one block. AS-1.

- D. Received in formalin labeled "subcarinal lymph node" is a 1.3 x 1.0 x 0.4 cm. portion of fragmented tan gold fatty tissue with a scant amount of gray black lymphoid tissue. [REDACTED] specimen is bisected and entirely submitted in one block. [REDACTED].

[REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

A-D. Microscopic examination of the left lower lobe of lung and the separate lymph node specimens reveals:

Histologic type: Adenocarcinoma, mucinous.
Histologic grade: Well-differentiated.
Primary tumor (pT): Tumor is 3 cm. in greatest dimension with no involvement of the pleura or a large stem bronchus (pT1b).
Margins of resection: The vascular and bronchial resection margins are all negative for tumor.

[page 2 of 2]
[REDACTED]

Direct extension of tumor: Tumor invades pulmonary parenchyma with no extension to pleura.
Venous (large vessel) invasion: Not identified.
Arterial (large vessel) invasion: Not identified.
Lymphatic (small vessel) invasion: Not identified.
Regional lymph nodes (pN): A single lymph node is dissected from the left lower lobe. Additional lymph nodes are present in level 10 and the separate left upper lobe lymph node and subcarinal lymph node all are negative for metastatic tumor (pN0).
Distant metastasis (pM): Cannot evaluate, pMx.
Other findings: The background pulmonary parenchyma is fairly unremarkable. The lymph nodes do show prominent anthracosis and some histiocytes associated with the anthracosis.
3x3, 5

DIAGNOSIS

- A. Lymph node, level 10, biopsy:
- Single lymph node negative for metastatic tumor (0/1).
- B. Lung, left lower lobe, lobectomy:
- Adenocarcinoma, mucinous, well-differentiated, 3 cm. in greatest dimension (pT1b).
- Single lymph node negative for metastatic tumor (0/1).
- No lymphovascular space invasion identified. Bronchial and vascular margins are negative for tumor.
- Background pulmonary parenchyma is relatively unremarkable.
- C. Lymph node, left upper lobe, biopsy:
- Single lymph node negative for metastatic tumor (0/1).
- D. Subcarinal lymph node, biopsy:
- Single lymph node negative for metastatic tumor (0/1).
- [REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 417d2959-a2dd-4e0f-a00f-cabae1700d93 (TCGA-44-6148.5407FF6D-A042-47DB-998B-60E6F15109AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).